Gene-level copy-number profile of tumor specimen C3N-04162-03 from CPTAC case C3N-04162, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 46.8 years (17,099 days).
Specimen C3N-04162-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e15c16e6-1184-482f-bffb-11793c100511.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-04162-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,727 have no estimate.
https://portal.gdc.cancer.gov/files/4a226de2-5c2a-4ac3-ba84-08f09f89d7cf

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 2,044; copy number 2: 16,174; copy number 3: 27,070; copy number 4: 8,391; copy number 5: 3,442; copy number 6: 1,575; copy number 7: 57; copy number 8: 106; copy number 9: 8; copy number 12: 1; copy number 13: 26.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:46,243,548–46,244,215, 1 gene: AC104072.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 198 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:90,114,838–90,154,574, 3 genes, copy number 9–12: IGKV3D-15, IGKV2D-14, IGKV1D-13.
- chr2:90,172,802–90,315,836, 8 genes, copy number 7–9: IGKV3D-11, IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8, IGKV3D-7, AC233263.2, IGKV1OR2-118.
- chr2:91,686,102–91,723,605, 2 genes, copy number 7: AC027612.2, NKAIN1P2.
- chr2:198,882,573–199,471,266, 5 genes, copy number 9 (within-gene range 2–9): AC020718.1, AC018717.1, RNU7-147P, SATB2, AC016746.1.
- chr7:130,070,534–130,142,618, 2 genes, copy number 7: KLHDC10, AC087071.1.
- chr11:8,693,351–8,910,951, 1 gene, copy number 7 (within-gene range 4–7): DENND2B.
- chr11:8,768,778–10,294,219, 40 genes, copy number 7 (within-gene range 3–7): AC026894.1, RNA5SP330, Y_RNA, AKIP1, C11orf16, ASCL3, Y_RNA, TMEM9B, TMEM9B-AS1, NRIP3, AC079296.1, SCUBE2, AC079296.2, MIR5691, KRT8P41, DENND5A, AP006259.1, Metazoa_SRP, TMEM41B, PRR13P2, IPO7, SNORA23, AC132192.1, AC132192.2, ZNF143, WEE1, AC122179.1, RPL23AP65, AC011979.2, AC011979.1, SWAP70, RN7SKP50, LINC02709, SBF2-AS1, SBF2, AC011092.2, RNU7-28P, AC011092.1, AC011092.3, AC100763.1.
- chr11:68,903,863–69,775,341, 26 genes, copy number 13: IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, CCND1, LTO1, FGF19, DNAJB6P5, FGF4.
- chr18:316,737–5,630,700, 106 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr21:12,999,676–13,120,807, 5 genes, copy number 7: AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Autosomal genes at a single copy (total copy number 1): 839. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
